Gene-level copy-number profile of tumor specimen TCGA-42-2582-01A from TCGA case TCGA-42-2582, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.2 years (17,961 days).
Specimen TCGA-42-2582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.299a7405-40f7-467c-9b5b-acb728df2859.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2582-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eef824c4-1cd0-40c6-97fc-e8c9abe08808

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 9,129; copy number 2: 39,762; copy number 3: 8,357; copy number 4: 1,538; copy number 5: 575; copy number 7: 455.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2582-01A-01D-1043-01): tumor purity 0.75, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:55,509,072–55,586,666, 3 genes (within-gene range 0–2): LPCAT2, AC007336.1, CAPNS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,030 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:193,842,560–198,222,513, 161 genes, copy number 5 (broad region; genes not listed).
- chr8:120,380,761–145,066,685, 455 genes, copy number 7 (broad region; genes not listed).
- chr19:7,112,255–14,471,867, 414 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
